Somatic mutation profile of tumor specimen TCGA-G9-6496-01A (aliquot TCGA-G9-6496-01A-11D-1786-08) from TCGA case TCGA-G9-6496, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.9 years (22,602 days).
Specimen TCGA-G9-6496-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb064b10-241c-4a99-b36e-233eb74f36e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6496-10A (Blood Derived Normal), aliquot TCGA-G9-6496-10A-01D-1786-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db056a96-62a2-453c-925b-ffd9f22feb6a

The open-access MAF lists 38 somatic variants for this specimen: 30 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 6, Intron 1, Frame Shift Ins 1, Splice Site 1, Frame Shift Del 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.3487A>G p.N1163D | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV55960754; called by muse, mutect2, varscan2
- AC109583.1 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1189019848, COSV59350277; called by muse, mutect2
- ACAP1 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs762483497, COSV50140089; called by muse, mutect2, varscan2
- ADGRB1 | c.3148C>T p.R1050C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV60102305; called by muse, mutect2, varscan2
- ADH1B | c.373C>A p.Q125K | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV59298230; called by muse, mutect2, varscan2
- ATRX | c.4667T>C p.M1556T | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV64881746; called by muse, mutect2, varscan2
- C19orf47 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs534758453, COSV63510823; called by muse, mutect2, varscan2
- CFAP126 | c.460T>C p.S154P | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.261); catalogued as COSV61369262; called by muse, mutect2, varscan2
- CTTNBP2 | c.3371T>A p.I1124N | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV50455637; called by muse, mutect2, varscan2
- DGKQ | c.2117A>G p.E706G | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53280646; called by muse, mutect2, varscan2
- EFCAB14 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV64240398; called by muse, mutect2, varscan2
- HSPA6 | c.455T>G p.F152C | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV59062288; called by muse, mutect2, varscan2
- IFT122 | c.774C>G p.D258E (on ENST00000348417 / NM_052989.3; = p.D199E on NM_018262.4) | Missense Mutation (SNP) | VAF 73/166 reads (44%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as COSV56206990; called by muse, mutect2, varscan2
- LAMA4 | c.4600A>C p.N1534H (on ENST00000230538 / NM_001105206.3; = p.N1527H on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57903316; called by muse, mutect2, varscan2
- MAP3K10 | c.581A>G p.H194R | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV53424682; called by muse, mutect2, varscan2
- MEGF10 | c.2104+1G>C p.X702_splice | Splice Site (SNP) | VAF 15/33 reads (45%) | catalogued as COSV57255045, COSV99175528; called by muse, mutect2, varscan2
- MKI67 | c.8891G>C p.R2964P | Missense Mutation (SNP) | VAF 64/215 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64076281; called by muse, mutect2, varscan2
- MUC16 | c.26054C>G p.T8685R | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.534); catalogued as rs1003634026, COSV67486800; called by muse, mutect2, varscan2
- MYLK | c.1357C>G p.P453A | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.794); catalogued as COSV60619432; called by muse, mutect2, varscan2
- NID1 | c.2702G>A p.R901H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs1462969325, COSV51626994; called by muse, mutect2, varscan2
- SLC45A4 | c.2105G>A p.G702D (on ENST00000517878 / NM_001286646.2; = p.G651D on NM_001080431.2) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs771581638, COSV50168724; called by muse, mutect2, varscan2
- SPAG16 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as rs142357329; called by muse, mutect2, varscan2
- TGOLN2 | c.1211A>G p.H404R | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56407267; called by muse, mutect2, varscan2
- TPTE2 | c.192G>T p.K64N | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV55026592, COSV99690909; called by muse, mutect2, varscan2
- TWF1 | c.909G>T p.L303F | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57300967, COSV57301700; called by muse, mutect2, varscan2
- ZZEF1 | c.2999A>C p.Q1000P | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV67559723; called by muse, mutect2
- DEPDC1B | c.1390_1394dup p.S466Nfs*11 | Frame Shift Ins (INS) | VAF 12/50 reads (24%) | called by pindel, varscan2
- IGHG1 | c.303A>C p.K101N | Missense Mutation (SNP) | VAF 94/231 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- OR51D1 | c.675_676del p.F226Hfs*50 | Frame Shift Del (DEL) | VAF 36/124 reads (29%) | called by pindel, varscan2
- PPP1R13B | c.2685_2687del p.S896del | In Frame Del (DEL) | VAF 38/113 reads (34%) | called by mutect2, pindel, varscan2
- CPS1 | c.4338C>T p.V1446= | Silent (SNP) | VAF 48/140 reads (34%) | catalogued as COSV51821478; called by muse, mutect2, varscan2
- CUX1 | c.2541C>T p.G847= | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as rs375527499; called by muse, mutect2
- SIRPB1 | c.61C>T p.L21= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as COSV54376865; called by muse, mutect2, varscan2
- SLC27A4 | c.360C>G p.A120= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV55961384; called by muse, mutect2, varscan2
- SSC4D | c.273C>T p.D91= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs542129562, COSV51881810; called by muse, mutect2, varscan2
- TET1 | c.5166G>A p.K1722= | Silent (SNP) | VAF 54/130 reads (42%) | catalogued as COSV65384507, COSV65388494; called by muse, varscan2
- AL353804.7 | chrX:73846553 G>T | 5'Flank (SNP) | VAF 69/88 reads (78%) | called by muse, mutect2, varscan2
- FBLN2 | c.2155+2048G>T | Intron (SNP) | VAF 12/39 reads (31%) | catalogued as rs748072635, COSV55489648; called by muse, mutect2, varscan2
